Surgical pathology report (de-identified scan), TCGA case TCGA-ZH-A8Y7, project TCGA-CHOL (Cholangiocarcinoma), tissue source site University of North Carolina, specimen TCGA-ZH-A8Y7-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Case Number :

ICDC:3
(Cholangiocarcinoma)
8166/3
Site: Intrahepatic bile duct
C22.1
p0 4/3/14

Diagnosis:

A: Gerota's fascia, biopsy

- Metastatic poorly differentiated adenocarcinoma
- See comment

B: Liver, definitive Segment 5 margin, biopsy

- Negative for malignancy
- Liver with increased portal fibrosis and periportal septae (stage 2), lobular acute inflammation and mild cholestasis
- See comment

C: Liver, Segments 1-4 and portion of 8, partial hepatectomy

Histologic tumor type/subtype: cholangiocarcinoma; see comment

Histologic grade: poorly differentiated

Tumor location: Segments 1-4 and portion of 8

Tumor size: 10 cm (gross measurement)

Focality/extent: Unifocal with diffuse involvement of nearly entire specimen

Tumor growth pattern: Mass forming

Tumor necrosis/treatment effect: Tumor appears approximately 25% necrotic

Vascular invasion: Present

Perineural invasion: Present, extensive

Capsular invasion: Absent; tumor abuts capsule but does not extend through it

Margins: - Negative for malignancy but close; tumor is 1 mm from the blue inked surgical margin, 1 mm from the green inked soft tissue margin, and 8 mm from the red inked margin (representing sutured area)

- Tumor present in soft tissue surrounding vascular structures from surgical margin (A1)

[page 2 of 4]
Lymph nodes: None received

Background liver: Mild lobular acute inflammation with cholestasis and portal fibrosis with periportal septae (stage 2)

Additional findings: Extensive biliary intraepithelial neoplasia (BilIN-3)

AJCC Pathologic TNM Stage: pT3 pNX

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

D: Gallbladder, cholecystectomy

- Negative for malignancy
- Minimal chronic cholecystitis with acute serositis

Comment:

Immunohistochemical stains are performed on block C10 and demonstrate the tumor shows patchy positivity for high molecular weight cytokeratin and CDX2, scant positivity for CK7, and is negative CK20. This immunophenotype is not entirely specific, however, the presence of extensive BilIN-3 and the positivity for high molecular weight cytokeratin leads us to favor the tumor being a primary cholangiocarcinoma rather than a metastatic lesion.

Intraoperative Consult Diagnosis:

A frozen section consultation was requested by Dr. in OR on
at (A) and (B).

FSA1: Gerota's fascia, biopsy

- Adenocarcinoma

Drs. on at

FSB1: Liver, definitive Segment 5 margin, biopsy

- No metastatic adenocarcinoma identified

Drs. at

Frozen Section Pathologist: , MD

[page 3 of 4]
Clinical History:

-year-old male with clinical diagnosis of cholangiocarcinoma.

Gross Description:

Received are four appropriately labeled containers. Specimens A and B are received fresh for frozen section.

Container A is received fresh for frozen section, and additionally labeled "Gerota's fascia." It holds a 9 x 6 x 5 mm red/tan soft tissue fragment; block FSA1, .

Container B holds one tan/brown liver fragment measuring 3.5 x 2.9 x 1.0 cm. (Block FSB1,)

Container C:

Specimen Type: left lobectomy (Segments #1-#4, and portions of #8)

Specimen Weight: 355 grams

Measurement: 12.5 x 12.0 x 4.5 cm

Orientation: The requisition states: stitch marks #1-#5 margin, and the specimen is received with a suture intact. The tissue surrounding the suture is inked red, the remainder of the cut surgical margin is inked blue, and a small amount of attached fatty soft tissue is inked green. Several staple lines across the surgical margin are removed, and the underlying tissue is re-inked blue.

Capsule: The capsule is notable for a 9.0 x 8.2 cm region of white/pink discoloration with underlying nodularity, although the surface remains smooth. This region of discoloration can be seen on both the anterior and posterior surfaces.

Mass: The mass measures 10.0 x 9.1 x 4.5 cm, and encompasses the majority of tissue in the specimen. It is white/pink with areas of red hemorrhage and yellow potential necrosis, is relatively firm, and is well circumscribed although with irregular borders and nodularity. It appears to abut the liver capsule on both sides, 0.1 from the red inked margin from the region of the stitch, and is 0.1 cm from the blue inked parenchymal margin. It is 0.4 cm from the green inked attached fatty soft tissue.

Adjacent liver tissue: The uninvolved liver tissue is tan/brown, firm and without additional lesions.

[page 4 of 4]
Major portal vein/ hepatic vein: Several vascular structures are present on the apparent surgical margin, and are removed and submitted en face. There is no gross evidence of vascular invasion.

Gallbladder: submitted separately

Block summary:

C1 - vascular structures from surgical margin, en face
C2 - section of tumor approaching red inked margin at stitch
C3 - section of tumor approaching red and blue ink
C4-C5 - additional section of mass close to blue inked surgical margins
C6 - mass with close approach to green inked overlying soft tissue
C7-C8 - bisected section of mass showing relationship with large vascular structure
C9-C10 - sections of mass abutting capsule, on both sides of the specimen
C11 - additional section of mass with apparent vascular structures
C12 - section of mass with adjacent uninvolved liver tissue
C13 - additional section of mass with capsule
C14 - edge of mass with possible extension into green inked fatty tissue
C15 - section of grossly uninvolved liver
Tissue remains in formalin.

Container D:

Previously opened or disrupted: no
Measurements: 8.0 x 3.5 x 2.7 cm
External surface: pink/green, smooth, and glistening with a roughened region showing tan/brown cautery on one surface
Luminal contents: approximately 15 cc of green, viscous, thin bile
Stones present: none
Mucosa: green/tan, smooth, and velvety
Wall thickness: 0.1 to 0.2 cm, and appears mildly edematous
Other comments: The cystic duct lymph node is not present
Block #: D1 cystic duct margin, en face, and representative sections of wall

Source: NCI Genomic Data Commons file d9f2cb79-d5c1-4220-9b1e-82fcc03be9dc (TCGA-ZH-A8Y7.3041BAB7-71A4-4DA3-A713-E81DDB237E95.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).